Gene-level copy-number profile of tumor specimen TCGA-VQ-A925-01A from TCGA case TCGA-VQ-A925, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 66.3 years (24,230 days).
Specimen TCGA-VQ-A925-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.e4d39111-0ce7-4d1d-9b76-306f2372e142.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A925-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e9f1440-89ea-430f-9dbe-197389afc680

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 34; copy number 2: 1,359; copy number 3: 10,387; copy number 4: 15,989; copy number 5: 14,136; copy number 6: 9,565; copy number 7: 5,193; copy number 8: 1,517; copy number 9: 596; copy number 10: 310; copy number 11: 116; copy number 12: 372; copy number 13: 133; copy number 16: 50; copy number 18: 4; copy number 21: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A925-01A-11D-A40Z-01): tumor purity 0.52, ploidy 4.9, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:151,409,176–151,670,503, 2 genes (within-gene range 0–4): FAM160A1, RN7SKP35.
- chr4:151,674,483–151,677,893, 1 gene: AC092611.1.
- chr17:11,953,889–12,215,267, 8 genes: AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2.
- chr17:46,029,916–46,225,389, 2 genes (within-gene range 0–3): KANSL1, CR936218.1.
- chr18:24,113,637–24,162,211, 5 genes: AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3.
- chr18:24,170,505–24,218,404, 3 genes: RNA5SP452, Metazoa_SRP, RNU6-435P.
- chr20:14,547,184–14,636,524, 2 genes: RNF11P2, MACROD2-IT1.
- chr20:14,884,250–14,935,363, 2 genes: MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 645 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:226,989,865–227,318,474, 1 gene, copy number 12 (within-gene range 4–12): CDC42BPA.
- chr1:227,178,333–227,846,470, 23 genes, copy number 12: AL451047.1, AL627308.1, AL627308.2, AL627308.3, LINC01641, NUCKS1P1, AL606462.1, BTF3P9, AL451054.2, AL451054.3, TUBB8P10, TUBB8P9, AL451054.1, AL451054.4, RNA5SP77, ZNF678, FAM133FP, ZNF847P, SNAP47, JMJD4, SNAP47-AS1, AL731702.1, PRSS38.
- chr1:234,356,704–235,161,283, 33 genes, copy number 16: AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34.
- chr1:235,190,034–235,190,116, 1 gene, copy number 16: MIR4753.
- chr3:149,162,410–149,503,394, 15 genes, copy number 21: CP, AC093001.2, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5.
- chr3:149,525,631–149,525,726, 1 gene, copy number 21: RNU6-1098P.
- chr3:158,496,561–158,496,934, 1 gene, copy number 12: AC106707.2.
- chr3:183,178,043–183,812,624, 15 genes, copy number 13 (within-gene range 7–13): MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1, KLHL24, YEATS2, YEATS2-AS1.
- chr3:183,815,922–183,825,594, 1 gene, copy number 13: MAP6D1.
- chr5:17,065,598–17,306,960, 8 genes, copy number 12: BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2, RNU6-1003P, AC026785.1.
- chr6:43,995,723–44,095,585, 5 genes, copy number 16: AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4.
- chr9:84,275,457–84,340,758, 2 genes, copy number 12: SLC28A3, AL356134.1.
- chr10:68,544,489–69,401,884, 29 genes, copy number 12 (within-gene range 6–12): TMEM14DP, TET1, COX20P1, RPS3AP37, AL513534.2, AL513534.3, CCAR1, Y_RNA, SNORD98, AL513534.1, STOX1, RNU6-697P, AL359844.1, DDX50, RNU6-571P, DDX21, KIFBP, MED28P1, ACTBP14, SRGN, Metazoa_SRP, VPS26A, RPS12P17, SUPV3L1, AL596223.1, HKDC1, AL596223.2, HK1, RPS15AP28.
- chr10:103,877,569–104,029,233, 3 genes, copy number 13 (within-gene range 8–13): STN1, SLK, RN7SL524P.
- chr10:121,133,090–121,598,458, 4 genes, copy number 12 (within-gene range 9–12): RPL19P16, LINC01153, RN7SKP167, FGFR2.
- chr12:68,957,377–71,118,247, 40 genes, copy number 12–18 (within-gene range 7–18): PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2.
- chr12:73,758,657–74,545,430, 11 genes, copy number 12: LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1.
- chr16:6,573,767–10,182,928, 52 genes, copy number 12 (within-gene range 9–12): AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2, TMEM114, AC138420.1, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, LITAFD, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195, AC007221.1, RNA5SP403, RNA5SP404, AC007218.1, GRIN2A, AC007218.2, AC007218.3.
- chr16:16,952,502–21,303,083, 116 genes, copy number 13–18 (within-gene range 7–18) (broad region; genes not listed).
- chr16:30,370,934–30,894,302, 51 genes, copy number 12 (within-gene range 6–12): MYLPF, ZNF48, SEPTIN1, AC116348.4, ZNF771, SNORA80C, DCTPP1, SEPHS2, Y_RNA, Y_RNA, ITGAL, AC116348.3, AC116348.1, RNU7-61P, AC116348.2, MIR4518, ZNF768, AC002310.4, AC002310.5, ZNF747, AC002310.1, AC002310.3, ZNF764, ZNF688, AC002310.2, ZNF785, AC093249.2, AC093249.4, ZNF689, AC093249.3, AC093249.5, AC093249.1, PRR14, FBRS, RNU6-416P, AC093249.6, SRCAP, RNU6-1043P, AC106886.5, SNORA30, TMEM265, AC106886.2, PHKG2, CCDC189, RNF40, AC106886.4, ZNF629, Metazoa_SRP, AC106886.1, AC106886.3, BCL7C.
- chr17:6,373,833–7,357,219, 70 genes, copy number 11 (broad region; genes not listed).
- chr17:38,914,979–41,425,049, 151 genes, copy number 12 (broad region; genes not listed).
- chr20:22,885,670–23,190,419, 12 genes, copy number 13–16: CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93, LINC00656, AL118508.2, RNA5SP478, AL118508.1.

Autosomal genes at a single copy (total copy number 1): 28. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
